Somatic mutation profile of tumor specimen TARGET-10-PARDNF-09A (aliquot TARGET-10-PARDNF-09A-01D) from TARGET case TARGET-10-PARDNF, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.7 years (3,916 days).
Specimen TARGET-10-PARDNF-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 50d44e8f-521c-44b6-8b3a-8b55513e5036.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARDNF-10A (Blood Derived Normal), aliquot TARGET-10-PARDNF-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/85538271-b11a-4b82-a9df-b4c23b57af7f

The open-access MAF lists 21 somatic variants for this specimen: 12 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 6, Intron 1, 3'Flank 1, Frame Shift Del 1, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYP51A1 | c.790C>T p.R264W | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.575); catalogued as rs372185409; called by muse, mutect2, varscan2
- ISY1-RAB43 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.236); catalogued as rs757823960; called by mutect2, varscan2
- MUC13 | c.1463G>C p.R488T | Missense Mutation (SNP) | VAF 60/150 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV60700166; called by muse, mutect2, varscan2
- RYK | c.1561G>A p.E521K (on ENST00000620660 / NM_001005861.2; = p.E518K on NM_002958.4) | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT tolerated (0.22); PolyPhen benign (0.039); catalogued as rs754659003, COSV56065170; called by muse, mutect2, varscan2
- SPATC1L | c.778C>T p.R260C (on ENST00000291672 / NM_001142854.2; = p.R106C on NM_032261.5) | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs569907908; called by muse, mutect2, varscan2
- ADGRG4 | c.4132C>A p.P1378T | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.362); called by muse, mutect2
- IGF1R | c.428T>C p.I143T | Missense Mutation (SNP) | VAF 88/174 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ILF3 | c.820A>T p.R274* | Nonsense Mutation (SNP) | VAF 21/48 reads (44%) | called by muse, mutect2, varscan2
- STX7 | c.257G>T p.R86M | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); called by muse, mutect2
- TP53 | c.833_856delinsGAGGC p.P278Rfs*61 | Frame Shift Del (DEL) | VAF 59/162 reads (36%) | called by pindel, varscan2*
- TRDV1 | c.320C>A p.A107E | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- WNT2B | c.372C>A p.D124E (on ENST00000369684 / NM_024494.3; = p.D105E on NM_004185.4) | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.261); called by muse, mutect2
- CABP2 | c.633C>T p.F211= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as COSV53708717; called by muse, mutect2, varscan2
- LRRN2 | c.387G>T p.L129= | Silent (SNP) | VAF 3/22 reads (14%) | called by muse, mutect2
- POLN | c.2436G>A p.P812= | Silent (SNP) | VAF 27/74 reads (36%) | catalogued as rs377189994; called by muse, mutect2, varscan2
- SPEG | c.4311C>T p.Y1437= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as rs772393925; ClinVar: likely benign; called by mutect2, varscan2
- STARD9 | c.11691C>A p.A3897= | Silent (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2
- ZSWIM6 | c.867C>A p.V289= | Silent (SNP) | VAF 5/59 reads (8%) | catalogued as COSV53174431; called by muse, mutect2
- MYL3 | chr3:46832989 T>A | 3'Flank (SNP) | VAF 5/20 reads (25%) | called by muse, mutect2, varscan2
- NOSTRIN | c.114-6356C>A | Intron (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2, varscan2
- SUMO2P21 | n.218C>T | RNA (SNP) | VAF 161/170 reads (95%) | called by muse, mutect2, varscan2
